Somatic mutation profile of tumor specimen TCGA-V5-A7RC-01B (aliquot TCGA-V5-A7RC-01B-11D-A403-09) from TCGA case TCGA-V5-A7RC, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; Tumor grade: GX; Age at diagnosis: 56.0 years (20,439 days).
Specimen TCGA-V5-A7RC-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1769cd4-28d8-4b0f-b19e-c9801252ab0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V5-A7RC-10A (Blood Derived Normal), aliquot TCGA-V5-A7RC-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dbd0af9-b45c-44cc-aac4-b087445bd5be

The open-access MAF lists 110 somatic variants for this specimen: 83 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 22, Frame Shift Del 5, Frame Shift Ins 4, Splice Site 4, Intron 4, Nonsense Mutation 2, In Frame Del 1, RNA 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 49/74 reads (66%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2239A>G p.S747G | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1240306616; called by muse, mutect2, varscan2
- ADAMTS19 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50765512; called by muse, mutect2, varscan2
- DCT | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175910242; called by muse, mutect2, varscan2
- DZIP3 | c.1234T>C p.F412L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as rs201610955; called by muse, mutect2, varscan2
- FMN2 | c.4865T>C p.I1622T | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1298917573, COSV60414894; called by muse, mutect2, varscan2
- FOXRED2 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs755978039; called by muse, mutect2, varscan2
- FRS3 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.253); catalogued as COSV99442694; called by muse, mutect2
- GABRA2 | c.1191C>A p.N397K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV62915598; called by muse, mutect2, varscan2
- GABRB1 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as COSV54971082; called by muse, mutect2, varscan2
- HNF4G | c.1051G>A p.G351R (on ENST00000354370 / NM_001330561.2; = p.G398R on NM_004133.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as COSV62967764; called by muse, mutect2, varscan2
- MAGEC1 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 72/112 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53577785; called by muse, mutect2, varscan2
- MPL | c.1433C>G p.S478W | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65246286; called by muse, mutect2
- PAPPA2 | c.42G>C p.L14F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100866688; called by muse, mutect2, varscan2
- PCDHGA3 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV54043100; called by muse, mutect2, varscan2
- POTEF | c.1880T>C p.V627A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1370646719; called by mutect2, varscan2
- RBBP6 | c.3675A>G p.I1225M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs767099633; called by muse, mutect2, varscan2
- SMC4 | c.3287A>G p.Y1096C | Missense Mutation (SNP) | VAF 141/184 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1257350404; called by muse, mutect2, varscan2
- SMPD4 | c.2143A>G p.I715V (on ENST00000409031 / NM_017951.4; = p.I686V on NM_017751.4) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs553662129; called by muse, mutect2, varscan2
- SPIRE1 | c.1059A>G p.P353= | Splice Region (SNP) | VAF 12/93 reads (13%) | catalogued as rs1161748131; called by muse, mutect2, varscan2
- TAS2R13 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.364); catalogued as rs749247763; called by muse, mutect2, varscan2
- ZIC4 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 24/221 reads (11%) | catalogued as rs201698839; called by muse, mutect2, varscan2
- ZNF142 | c.5098C>T p.R1700W (on ENST00000411696 / NM_001379660.1; = p.R1500W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs367658234; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACSF3 | c.40T>C p.C14R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.024); called by muse, mutect2
- AKIRIN2 | c.331T>G p.S111A | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARHGAP36 | c.526C>G p.P176A | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATAD2 | c.1921T>C p.S641P | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CFAP221 | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CRNKL1 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- DNAH2 | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ECSIT | c.1280A>T p.Q427L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EML3 | c.2116A>G p.I706V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ETAA1 | c.327del p.N110Ifs*4 | Frame Shift Del (DEL) | VAF 55/186 reads (30%) | called by mutect2, pindel, varscan2
- FAT1 | c.6195_6197del p.V2067del | In Frame Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- FAT3 | c.1404C>G p.H468Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- FLOT2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GTF2F1 | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2
- H2AC12 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HAX1 | c.778_799del p.A260Sfs*34 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- HBE1 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- HMGCR | c.277+1G>C p.X93_splice | Splice Site (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- IKZF2 | c.1522A>G p.S508G | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ISL1 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KNDC1 | c.1966C>A p.Q656K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LCE2B | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRRC4B | c.2018A>G p.H673R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- METTL22 | c.605_612del p.D202Afs*16 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- MOSPD3 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MROH9 | c.460G>C p.V154L | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2
- MUC16 | c.10631_10633dup p.T3544dup | In Frame Ins (INS) | VAF 18/96 reads (19%) | called by mutect2, varscan2
- NAT16 | c.312+1G>C p.X104_splice | Splice Site (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- NOTCH3 | c.3009G>A p.W1003* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- ODC1 | c.1277del p.P426Hfs*4 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel
- OR56A3 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- OTUD7B | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PANK3 | c.598C>A p.H200N | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- PHC3 | c.503C>T p.A168V (on ENST00000494943 / NM_001308116.2; = p.A180V on NM_024947.4) | Missense Mutation (SNP) | VAF 211/308 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PLEKHA8 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- POLRMT | c.666G>C p.Q222H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- PPT1 | c.698C>G p.S233C (on ENST00000433473; = p.S234C on NM_000310.4) | Missense Mutation (SNP) | VAF 1144/1267 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PTCH1 | c.2606dup p.M869Ifs*27 | Frame Shift Ins (INS) | VAF 57/116 reads (49%) | called by mutect2, pindel, varscan2
- RIMS1 | c.2320G>C p.D774H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPS6KA2 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEC63 | c.624+2T>G p.X208_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- SERPINB4 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SIGLEC7 | c.36dup p.R13Efs*10 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- SLC13A4 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SLITRK2 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLITRK4 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SMAD2 | c.527C>G p.P176R | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SMCR8 | c.473del p.I158Tfs*26 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- SORCS1 | c.1376G>C p.R459T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SPAG17 | c.3383dup p.N1128Kfs*20 | Frame Shift Ins (INS) | VAF 13/93 reads (14%) | called by pindel, varscan2
- SYDE2 | c.1779dup p.L594Sfs*2 | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- TBC1D14 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- THPO | c.460C>G p.L154V (on ENST00000649095 / NM_001290003.1; = p.L14V on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.671); called by muse, mutect2
- TTN | c.61878A>C p.L20626F (on ENST00000591111; = p.L13202F on NM_003319.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | PolyPhen possibly damaging (0.66); called by muse, varscan2
- UCHL5 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- VSX2 | c.610A>G p.R204G | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZIK1 | c.123G>C p.W41C | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF300 | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF540 | c.1101T>A p.S367R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF688 | c.664A>G p.R222G | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP9B | c.150G>A p.L50= | Silent (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- CDRT1 | c.99C>A p.V33= | Silent (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- CHST8 | c.1005C>T p.C335= | Silent (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- CLK3 | c.1893C>T p.H631= (on ENST00000395066 / NM_001130028.1; = p.H483= on NM_003992.4) | Silent (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- COL11A1 | c.4176C>A p.T1392= | Silent (SNP) | VAF 21/223 reads (9%) | catalogued as rs750903509, COSV100616854; called by muse, mutect2, varscan2
- CPZ | c.1158G>A p.V386= (on ENST00000360986 / NM_001014447.3; = p.V375= on NM_003652.3) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1028411489; called by muse, mutect2, varscan2
- FAM135B | c.1125G>T p.L375= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- FANCM | c.675T>C p.Y225= | Silent (SNP) | VAF 42/57 reads (74%) | called by muse, mutect2, varscan2
- FCSK | c.699C>T p.A233= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs753351332; called by muse, mutect2, varscan2
- FGF10 | c.336G>A p.E112= | Silent (SNP) | VAF 56/189 reads (30%) | catalogued as rs1268706232; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1698G>A p.R566= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- NCOA5 | c.64C>A p.R22= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV51645598; called by muse, mutect2, varscan2
- NEK9 | c.2673G>A p.A891= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs145167526; called by muse, mutect2, varscan2
- PCDHB8 | c.1419C>T p.S473= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs113701735, COSV50768308; called by muse, mutect2, varscan2
- PLXNA1 | c.4830C>T p.I1610= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- RNF220 | c.1560G>A p.S520= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs561320190; called by muse, mutect2, varscan2
- RYR2 | c.12375C>G p.V4125= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1434635546; called by muse, mutect2, varscan2
- SLC25A11 | c.921C>T p.Y307= | Silent (SNP) | VAF 30/40 reads (75%) | called by muse, mutect2, varscan2
- SLC35G3 | c.510C>T p.I170= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as rs749966552; called by muse, mutect2, varscan2
- STK24 | c.426A>G p.K142= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs768243797; called by muse, mutect2, varscan2
- SYNC | c.1242G>A p.L414= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.1740G>A p.T580= | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as rs779385993; called by muse, mutect2, varscan2
- ANKS1B | c.3067-6752A>G | Intron (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- DNM1P46 | n.327G>A | RNA (SNP) | VAF 25/163 reads (15%) | catalogued as rs749937025; called by muse, mutect2, varscan2
- NACA | c.70+3484_70+3485del | Intron (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- SND1 | c.1779+6756del | Intron (DEL) | VAF 29/76 reads (38%) | catalogued as COSV100689508; called by mutect2, pindel, varscan2
- XPO7 | c.492+18C>A | Intron (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
